Somatic mutation profile of tumor specimen MP2PRT-PAPHNJ-TMP1-A (aliquot MP2PRT-PAPHNJ-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPHNJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,271 days).
Specimen MP2PRT-PAPHNJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2184acb-dbb1-4c1c-b4b7-249a9a06b3b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHNJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHNJ-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/724768a5-46e2-4c0a-9915-360ce4045aec

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.2680G>C p.A894P | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV65895965; called by muse, mutect2
- AKT3 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55609925; called by muse, mutect2, varscan2
- C9orf43 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 146/328 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142991325, COSV55912773; called by muse, varscan2
- CYB5R2 | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV55087670; called by muse, mutect2, varscan2
- DRD5 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 184/412 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.07); catalogued as rs776907638, COSV100431435; called by muse, mutect2, varscan2
- FBXO34 | c.100A>C p.N34H | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100571922; called by muse, mutect2, varscan2
- FSCN2 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197301508; called by muse, mutect2
- HR | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs772209791; called by muse, mutect2, varscan2
- IL7R | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 108/504 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV57406053, COSV57408353; called by muse, mutect2
- IPO9 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV64233191; called by muse, mutect2, varscan2
- LYZL1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs551593769, COSV64966116; called by muse, mutect2, varscan2
- MED9 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.113); catalogued as rs1179631578; called by muse, mutect2, varscan2
- PKD1 | c.4475G>A p.R1492H | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs757055929, COSV51919655; called by muse, mutect2, varscan2
- PSG4 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs759940767; called by muse, mutect2, varscan2
- SF3B1 | c.3099G>T p.E1033D | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59225395; called by muse, mutect2, varscan2
- SGCZ | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs761534961, COSV66019533, COSV66027498; called by muse, mutect2, varscan2
- SPATA31E1 | c.3374C>A p.A1125D | Missense Mutation (SNP) | VAF 100/484 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV57792425; called by muse, mutect2, varscan2
- UNC80 | c.9410G>A p.S3137N | Missense Mutation (SNP) | VAF 66/469 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs1164997866, COSV55890417; called by muse, mutect2, varscan2
- CACNA1E | c.6485T>C p.V2162A (on ENST00000367573 / NM_001205293.3; = p.V2119A on NM_000721.4) | Missense Mutation (SNP) | VAF 128/391 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by mutect2, varscan2
- FBXW5 | c.1655_1656insT p.R553Tfs*28 | Frame Shift Ins (INS) | VAF 80/459 reads (17%) | called by mutect2, pindel, varscan2
- GPR37L1 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 124/555 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2
- GTPBP6 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 95/376 reads (25%) | called by muse, mutect2, varscan2
- KDM6A | c.3337_3338insGCCCCCTGAGAGTGTCG p.V1113Gfs*13 | Frame Shift Ins (INS) | VAF 106/130 reads (82%) | called by mutect2, pindel, varscan2
- SLC18A2 | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SYNE1 | c.5612C>A p.A1871E (on ENST00000367255 / NM_182961.4; = p.A1878E on NM_033071.3) | Missense Mutation (SNP) | VAF 224/507 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRT71 | c.735C>T p.Y245= | Silent (SNP) | VAF 15/451 reads (3%) | catalogued as rs1433787129, COSV99921988; called by muse, mutect2
- NCF1 | c.132C>T p.F44= | Silent (SNP) | VAF 64/168 reads (38%) | called by muse, varscan2
- PHKB | c.1095T>C p.F365= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as rs1387187605; called by muse, mutect2, varscan2
- TNNI3K | c.1983C>A p.G661= | Silent (SNP) | VAF 46/282 reads (16%) | catalogued as rs187479159; called by muse, mutect2, varscan2
